HCMI case HCM-BROD-0678-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/79858538-bc27-4abd-9b42-16659ad5da56

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2018; Vital status: Dead; Days to death: 17 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Large cell medulloblastoma: ICD-O-3 morphology code: 9474/3; ICD-10 code: C71.6; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 1.2 years (445 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Medulloblastoma molecular classification: Not Determined.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 13 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 17 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Karnofsky performance status: 0.

Molecular and laboratory tests
- MYCN amplification: Amplified.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 8 kg; Height: 73 cm; BMI: 15.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0678-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0678-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 9.
